Gene-level copy-number profile of tumor specimen TCGA-FS-A1ZJ-06A from TCGA case TCGA-FS-A1ZJ, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 78.1 years (28,524 days).
Specimen TCGA-FS-A1ZJ-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.8e8a16f3-ec09-4eb9-807d-f504218307fb.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-FS-A1ZJ-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 817 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/4b580fbb-991a-4751-b882-9bb083d15d59

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 163; copy number 1: 16,653; copy number 2: 34,831; copy number 3: 4,096; copy number 4: 3,671; copy number 5: 207; copy number 6: 181; copy number 7: 4.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-FS-A1ZJ-06A-12D-A191-01): tumor purity 0.94, ploidy 1.95, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 163 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:181,064,089–181,265,145, 3 genes: LINC00290, AC019235.1, LINC02500.
- chr4:186,069,155–190,092,279, 82 genes (broad region; genes not listed).
- chr6:136,822,564–137,219,449, 11 genes (within-gene range 0–1): PEX7, AL121933.1, AL365223.1, SLC35D3, Y_RNA, RPL35AP3, NHEG1, AL135902.1, IL20RA, IL22RA2, IFNGR1.
- chr9:21,140,214–22,128,103, 49 genes: IFNW1, Y_RNA, IFNA21, IFNWP15, IFNA4, IFNWP9, IFNA7, IFNA10, IFNWP18, IFNA16, IFNA17, IFNWP5, IFNA14, IFNA22P, IFNA5, IFNA20P, KLHL9, IFNA6, IFNA13, IFNA2, AL353732.1, IFNA11P, IFNA12P, IFNA8, AL353732.2, IFNWP2, IFNA1, MIR31HG, IFNWP19, IFNE, MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2.
- chr10:44,712–254,637, 6 genes: AL713922.1, TUBB8, IL9RP2, ZMYND11, AL713922.2, RNA5SP297.
- chr10:282,015–282,125, 1 gene: RNA5SP298.
- chr11:12,674,421–13,387,266, 11 genes (within-gene range 0–2): TEAD1, AC013549.3, AC013549.4, AC013549.2, AC013549.1, LINC00958, RASSF10-DT, RASSF10, AC013762.1, AC022878.1, ARNTL.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 392 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:218,285,293–221,134,221, 57 genes, copy number 5: RRP15, AC096638.2, AC096638.1, TGFB2-AS1, TGFB2, TGFB2-OT1, LINC02869, U3, NXNP1, LINC01710, LYPLAL1-DT, LYPLAL1, RIMKLBP2, AL360093.1, AC096642.1, AC096642.2, LYPLAL1-AS1, AL356364.1, ZC3H11B, SLC30A10, RNA5SP76, U3, EPRS1, BPNT1, IARS2, MIR215, MIR194-1, RPS15AP12, RAB3GAP2, MIR664A, SNORA36B, SNX2P1, KF455155.1, MORF4L1P1, AURKAP1, XRCC6P3, AL451081.2, AL451081.1, AC096644.3, AC096644.2, AC096644.1, PRELID3BP1, LINC02779, MARK1, RN7SL464P, HDAC1P2, C1orf115, MTARC2, MTARC1, AL445423.3, RNU6ATAC35P, AL445423.2, AL445423.1, LINC01352, HLX-AS1, HLX, AL445466.1.
- chr4:5,014,586–5,814,305, 7 genes, copy number 5 (within-gene range 4–5): CYTL1, STK32B, Y_RNA, RN7SKP275, LINC01587, EVC2, EVC.
- chr4:27,207,505–27,985,063, 7 genes, copy number 6: AC024132.1, LINC02261, Y_RNA, AC024132.3, IGBP1P5, AC007106.2, AC007106.1.
- chr4:41,842,154–42,657,105, 16 genes, copy number 5 (within-gene range 4–5): HMGB1P28, LINC00682, AC108210.1, AC108210.2, TMEM33, DCAF4L1, AC106052.1, SLC30A9, ATP1B1P1, BEND4, AC111006.1, AC024022.1, SHISA3, ATP8A1, RPS7P7, CCNL2P1.
- chr4:51,843,000–59,630,324, 137 genes, copy number 5–7 (broad region; genes not listed).
- chr4:148,078,762–149,278,123, 13 genes, copy number 6 (within-gene range 1–6): NR3C2, AC069272.1, AC002460.2, ASS1P8, RNA5SP166, AC108935.1, ATP5MGP4, AC093648.1, AC002460.1, RNU7-197P, AC108156.1, LINC02430, LINC02355.
- chr9:26,642,697–27,944,497, 26 genes, copy number 5: AL442639.1, AL451137.2, AL451137.1, AL356133.1, CAAP1, H3P31, RN7SL100P, PLAA, IFT74, IFT74-AS1, LRRC19, AL355432.1, TEK, RNA5SP280, AL355433.1, LINC00032, EQTN, MOB3B, AL163192.1, AL451123.2, IFNK, AL451123.1, C9orf72, CTAGE12P, AL360014.1, AL353746.1.
- chr13:29,764,371–32,954,401, 63 genes, copy number 6 (broad region; genes not listed).
- chr13:53,815,419–55,583,524, 12 genes, copy number 6: LINC00558, LINC00458, AL356052.1, MIR1297, RPL13AP25, AL442636.1, AL512655.1, AL390964.1, LINC02335, AL139038.1, MIR5007, AL354821.1.
- chr17:14,834,557–14,957,216, 2 genes, copy number 6 (within-gene range 1–6): LINC02096, RPL23AP76.
- chr17:15,699,692–15,744,778, 1 gene, copy number 5 (within-gene range 1–5): AC005324.3.
- chr17:15,732,247–15,847,996, 13 genes, copy number 5: TBC1D26, TBC1D26-AS1, AC005324.5, AC005324.1, CDRT15P2, ZSWIM5P1, RNA5SP436, IL6STP1, MEIS3P1, AC015922.2, AC015922.3, AC015922.1, LINC02087.
- chr17:21,678,086–22,568,713, 29 genes, copy number 5: AC233702.9, KCNJ18, AC243725.1, ABBA01006766.1, NCOR1P2, UBBP4, FTLP13, LINC02002, AC138761.1, AC138761.2, FAM27E5, AC087575.1, FLJ36000, AC132825.3, AC132825.4, MTND6P35, MTCYBP13, MTRNR2L1, AC132825.2, MTND1P15, MTND2P13, AC132825.1, NMTRS-TGA3-1, MTATP6P3, MTCO3P13, AC132825.6, AC132825.7, AC132825.5, AC131055.2.
- chr20:57,895,394–58,367,507, 9 genes, copy number 5 (within-gene range 4–5): AL162291.1, AL354984.1, LINC01742, AL354984.2, AL354984.3, C20orf85, ANKRD60, PPP4R1L, RAB22A.

Autosomal genes at a single copy (total copy number 1): 15,377. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
